Somatic mutation profile of tumor specimen TCGA-CZ-5466-01A (aliquot TCGA-CZ-5466-01A-01D-1501-10) from TCGA case TCGA-CZ-5466, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.5 years (24,669 days).
Specimen TCGA-CZ-5466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfe2ecca-8a50-4c97-b00e-d1adae1430bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5466-11A (Solid Tissue Normal), aliquot TCGA-CZ-5466-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a631990d-9e17-4868-bd18-8fd70828c305

The open-access MAF lists 63 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Nonsense Mutation 6, Frame Shift Del 3, 3'UTR 2, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.983C>A p.T328N | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52636262; called by muse, mutect2, varscan2
- APBB3 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60051601; called by muse, mutect2, varscan2
- APC | c.7621A>G p.I2541V | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs587778033, CM080039, COSV57327926; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- AVIL | c.1431G>C p.R477S | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57680646; called by muse, mutect2, varscan2
- CCDC158 | c.1053A>C p.L351F | Missense Mutation (SNP) | VAF 88/458 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66355298; called by muse, mutect2
- CCNB2 | c.616A>T p.K206* | Nonsense Mutation (SNP) | VAF 46/241 reads (19%) | catalogued as COSV55594939; called by muse, mutect2, varscan2
- CDC20 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV60521756; called by muse, mutect2, varscan2
- CLSTN2 | c.533T>C p.I178T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV101515934; called by muse, mutect2, varscan2
- DBN1 | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV52787800; called by muse, mutect2, varscan2
- DIS3 | c.1126G>C p.A376P | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV66705725; called by muse, mutect2, varscan2
- DOCK2 | c.4069C>T p.R1357W | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177166833, COSV56944614; called by muse, mutect2, varscan2
- DSEL | c.1553C>G p.S518* | Nonsense Mutation (SNP) | VAF 20/143 reads (14%) | catalogued as COSV59489753; called by muse, mutect2, varscan2
- HRNR | c.2563G>A p.G855S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as rs202201629; called by muse, mutect2, varscan2
- HSPA8 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57082798; called by muse, mutect2, varscan2
- ITGA7 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as COSV57692452; called by muse, mutect2, varscan2
- IVL | c.459G>T p.L153F | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs1193602038, COSV64215652; called by muse, mutect2
- KDM5B | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 155/810 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs765016028, COSV52504882; called by muse, mutect2, varscan2
- KIAA1549L | c.4145A>G p.E1382G (on ENST00000321505; = p.E1679G on NM_012194.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58582790; called by muse, varscan2
- KIF14 | c.767A>G p.H256R | Missense Mutation (SNP) | VAF 118/618 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV66260103; called by muse, mutect2, varscan2
- MDN1 | c.16220C>G p.S5407C | Missense Mutation (SNP) | VAF 66/364 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65517970; called by muse, mutect2, varscan2
- METTL7B | c.498G>A p.P166= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as rs144071589; called by mutect2, varscan2
- MFSD2A | c.1581C>A p.S527R (on ENST00000372809 / NM_001136493.3; = p.S514R on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65685054; called by muse, mutect2, varscan2
- MKRN3 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs939910352, COSV58808843; called by muse, mutect2, varscan2
- MYH6 | c.1793dup p.N598Kfs*38 | Frame Shift Ins (INS) | VAF 26/153 reads (17%) | catalogued as rs774500922; called by mutect2, varscan2
- NUAK2 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65680913; called by muse, varscan2
- OR11L1 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV63313782, COSV63315888; called by muse, mutect2, varscan2
- PBRM1 | c.2363C>A p.S788* | Nonsense Mutation (SNP) | VAF 40/191 reads (21%) | catalogued as COSV56263384, COSV56264640; called by muse, mutect2, varscan2
- PCDHB1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60629666; called by muse, mutect2, varscan2
- PDGFRA | c.2809C>G p.P937A | Missense Mutation (SNP) | VAF 85/471 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.196); catalogued as COSV57265347; called by muse, mutect2, varscan2
- PRKACB | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 78/438 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV65762167; called by muse, mutect2, varscan2
- PRPF31 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs780317796, COSV58086665; called by muse, mutect2
- PRTG | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs144541725, COSV66836982; called by muse, mutect2, varscan2
- RABGEF1 | c.616A>T p.M206L (on ENST00000439720 / NM_001287061.2; = p.M193L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768728920, COSV53160946; called by muse, mutect2, varscan2
- RANBP2 | c.4100C>T p.S1367L | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV51697115; called by muse, mutect2, varscan2
- SLC22A7 | c.1633C>T p.Q545* (on ENST00000372585 / NM_153320.2; = p.Q543* on NM_006672.3) | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV51483072; called by muse, mutect2, varscan2
- SLC22A9 | c.1328T>A p.L443* | Nonsense Mutation (SNP) | VAF 31/180 reads (17%) | catalogued as COSV54166067; called by muse, mutect2, varscan2
- SLC24A3 | c.1257G>C p.E419D | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV60113266; called by muse, mutect2, varscan2
- SLC4A8 | c.3121C>A p.P1041T | Missense Mutation (SNP) | VAF 84/488 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV71615116; called by muse, mutect2, varscan2
- SLC9A3 | c.2207T>A p.F736Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV53799338; called by muse, mutect2, varscan2
- SUN1 | c.1991G>T p.S664I (on ENST00000405266 / NM_001367651.1; = p.S544I on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67447982; called by muse, mutect2, varscan2
- UBTF | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.491); catalogued as COSV100256154; called by muse, mutect2, varscan2
- YWHAB | c.588G>A p.T196= | Splice Region (SNP) | VAF 21/142 reads (15%) | catalogued as COSV53844642, COSV99408417; called by muse, mutect2, varscan2
- ZBTB44 | c.761T>A p.L254* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as COSV63536820; called by muse, mutect2, varscan2
- ZNF112 | c.169A>C p.I57L (on ENST00000337401 / NM_001083335.2; = p.I51L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV61618960, COSV61621823; called by muse, mutect2, varscan2
- ZNF426 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV53468393; called by muse, mutect2, varscan2
- ZNF609 | c.2122C>G p.P708A | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV58580349; called by muse, mutect2, varscan2
- ARL6IP6 | c.568_569del p.L190Ffs*18 | Frame Shift Del (DEL) | VAF 68/437 reads (16%) | called by pindel, varscan2
- DYRK1B | c.911_912del p.V304Gfs*14 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by pindel, varscan2
- RECK | c.1063dup p.Y355Lfs*4 | Frame Shift Ins (INS) | VAF 69/333 reads (21%) | called by mutect2, pindel, varscan2
- STAG2 | c.1543_1544del p.D515* | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- APOBEC3B | c.126G>A p.K42= | Silent (SNP) | VAF 21/168 reads (13%) | catalogued as COSV59840379; called by muse, mutect2, varscan2
- CABIN1 | c.1585C>T p.L529= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV54078384; called by muse, mutect2, varscan2
- CAV3 | c.441G>A p.L147= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV57478519; called by muse, mutect2, varscan2
- CLSTN3 | c.1554G>T p.S518= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs756157048, COSV56934311; called by muse, mutect2, varscan2
- DDX24 | c.2280G>A p.E760= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV52572801; called by muse, mutect2, varscan2
- DNM1L | c.1479T>C p.Y493= | Silent (SNP) | VAF 187/1274 reads (15%) | catalogued as COSV56772557; called by muse, mutect2, varscan2
- MFSD5 | c.969C>G p.V323= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV61565175; called by muse, mutect2, varscan2
- SAMD4A | c.873G>A p.L291= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV51877294; called by muse, mutect2, varscan2
- SLC25A14 | c.369G>T p.G123= | Silent (SNP) | VAF 75/222 reads (34%) | catalogued as COSV54417041; called by muse, mutect2, varscan2
- TNFAIP3 | c.1932C>T p.V644= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV52796982; called by muse, mutect2, varscan2
- ZUP1 | c.636T>G p.V212= | Silent (SNP) | VAF 67/382 reads (18%) | catalogued as COSV63943990; called by muse, mutect2, varscan2
- MAT2A | c.*1A>C | 3'UTR (SNP) | VAF 16/100 reads (16%) | catalogued as COSV99290207; called by muse, mutect2, varscan2
- SLC35A3 | c.*171T>C | 3'UTR (SNP) | VAF 85/445 reads (19%) | catalogued as COSV64515728; called by muse, mutect2, varscan2
